MMRF case MMRF_1648 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ff7f4510-d7d6-4279-a01d-0c9409852b4e

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.3 years (23,127 days); ISS stage: I; Days to last known disease status: 58 days; Days to last follow up: 58 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 105 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.585 mg/dL; Immunoglobulin G 5.26 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.07 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.5 mmol/L; Albumin 46 g/L; Total Protein 6.8 g/dL; Glucose 5.56 mmol/L; C-Reactive Protein 0.44 mg/dL.
- Day 58 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 130 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.545 mg/dL; Immunoglobulin G 9.14 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 3.11 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day -17: Weight: 69 kg; Height: 160 cm.

Biospecimens (2 samples)
- Sample MMRF_1648_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_1648_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
